Surgical pathology report (de-identified scan), TCGA case TCGA-24-1424, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1424-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- HIGH GRADE SEROUS CARCINOMA

FALLOPIAN TUBES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- HIGH GRADE SEROUS CARCINOMA INVOLVING BOTH FALLOPIAN TUBES
- FIBROUS ADHESIONS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- HIGH GRADE SEROUS CARCINOMA

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- LEIOMYOMAS (LARGEST = 5.3 CM)

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- INACTIVE ENDOMETRIUM WITH MINUTE ENDOMETRIAL POLYP

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- HIGH GRADE SEROUS CARCINOMA INVOLVING PERICERVICAL SOFT TISSUE

LARGE INTESTINE, SIGMOID COLON, EXCISION
- HIGH GRADE SEROUS CARCINOMA INVOLVING FRAGMENTS OF SMOOTH MUSCULAR TISSUE

OMENTUM, EXCISION
- HIGH GRADE SEROUS CARCINOMA (MULTIFOCAL; LARGEST FOCUS = 4.2 CM)

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

[page 2 of 3]
Specimen(s) Received:

A: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES
B: SIGMOID
C: OMENTUM

Gross Description:

The specimens are received in three formalin-filled containers, each labeled [REDACTED]. The first container is labeled "uterus, ovaries, tubes, cervix." It contains a 122-gram uterus and cervix, and detached bilateral adnexa. The larger adnexa includes an 11.0 x 6.5 x 4.8 cm solid and multicystic purple-pink-yellow mass that replaces the ovary, with exophytic tumor on the surface of the ovary. Sections show the mass is largely comprised of spongy, heterogeneous white and yellow tissue with additional cystic areas. No definite residual normal ovarian parenchyma is identified. The 4.2 cm long x 0.6 cm diameter portion of tan-purple fallopian tube has a proximal portion with tumor nodules on its surface. Sections show probable involvement of the tubal wall by the tumor. The smaller adnexa includes a 5.8 x 4.9 x 3.8 cm yellow-tan ovarian mass. The surface of the mass is exophytic, and shows a 2.0 cm diameter disruption. Sections of the ovarian mass show a 3.0 cm diameter cystic portion, with papillary excrescences on the otherwise smooth cyst lining. There is gross, diffuse involvement of the surface of the ovary by the tumor. The specimen includes a 3.5 cm long x 0.6 cm diameter tan-purple fallopian tube with an unremarkable fimbriated end. The surface of the fallopian tube shows minute (0.1 cm) nodules that may represent tumor nodules. Sections of the fallopian tube show an unremarkable lumen. The 6.8 (cornu to cornu) x 9.5 (fundus to ectocervix) x 6.0 cm (anterior to posterior) uterus and cervix is covered by tan serosa. The uterine contour is distorted by a 5.3 cm fibroid anteriorly. The serosa has hemorrhagic areas, and adhesions that may represent tumor implants. The 3.4 cm diameter cervix is covered by smooth white mucosa, and has an unremarkable 0.8 cm diameter external os. The uterus and cervix are opened to show an unremarkable 1.9 cm long x 0.3 cm diameter endocervical canal, lined by shiny mucosa. The 2.8 x 1.4 cm endometrial cavity is lined by pink endometrium. There is a 0.5 cm diameter pink polypoid mass with a very thin stalk near the fundus. There is a second 0.7 cm diameter pink polypoid mass with a narrow stalk attached to the lower uterine segment portion of the endometrial cavity. Sections of the cervix show no masses. Sections of the endomyometrium show a maximum endometrial thickness of 0.1 cm. The myometrium (without fibroids) is up to 1.9 cm thick and is comprised of unremarkable spongy tan tissue. Additional small intramural fibroids are identified, comprised of firm, whorled tissue. The large anterior fibroid is sectioned to show firm, whorled, white tissue, without necrosis or hemorrhage. Labeled A1 - larger ovarian tumor, with surface involvement; A2 - cystic portion of larger ovarian tumor with putative residual normal ovarian tissue; A3 and A4 - solid portions of larger ovarian tumor; A5 - fallopian tube with involvement by tumor from larger adnexa; A6 to A9 - smaller ovary; A10 - fallopian tube within smaller adnexa; A11 - anterior cervix; A12 - posterior cervix; A13 - anterior lower uterine segment endometrium, with polypoid lesion, and detached polypoid endometrial lesion from fundus; A14 - anterior endomyometrium; A15 - posterior endomyometrium; A16 - posterior uterine serosa and myometrium; A17 - portion of largest fibroid. Jar 2.

The second container is labeled "sigmoid tumor." It contains a 1.2 cm diameter tan-white nodule, similar to tumor seen on the ovaries. Sectioned. Labeled B1. [REDACTED]

The third container is labeled "omentum." It contains a 39.5 x 11.8 x 2.5 cm portion of yellow-tan omentum. There are multiple tumor nodules visible on the surface. Sections show multiple tan, fleshy, and firm tumor nodules, measuring up to 4.2 cm in diameter. The nodules occupy approximately 20% of the volume of the omentum. Labeled C1. Jar 2.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

[page 3 of 3]
TUMOR LOCATION

Right and left ovary

HISTOLOGIC GRADE

The histologic grade is poorly differentiated

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES

The regional lymph nodes cannot be assessed

DISTANT METASTASIS

The status of distant tumor site cannot be assessed

STAGE GROUPING

T3c/NX/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file c106466c-4172-47b5-a844-51b88eadd172 (TCGA-24-1424.2B1DFCC6-E4EE-4443-9472-171569244648.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).